Somatic mutation profile of tumor specimen C3L-00902-02 (aliquot CPT0063320009) from CPTAC case C3L-00902, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 69.8 years (25,512 days).
Specimen C3L-00902-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f44b598-e5a1-4d71-923e-dcd71c2ef311.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00902-31 (Blood Derived Normal), aliquot CPT0065240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54e95cc0-bab6-4da8-bc4b-33f03006f07f

The open-access MAF lists 114 somatic variants for this specimen: 77 protein-altering or splice-affecting, 20 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 20, Intron 9, Frame Shift Ins 5, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, 3'UTR 2, 5'UTR 2, RNA 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 116/397 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559429824, CD962181, CM114581, CM951299, CM982013, COSV56546651, COSV56549626, COSV56559142, COSV56568527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGBL1 | c.1337G>T p.S446I | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV66850597; called by muse, mutect2, varscan2
- CEP95 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56748585; called by mutect2, varscan2
- CRAMP1 | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1481337275; called by muse, mutect2, varscan2
- DVL2 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs776226256; called by muse, mutect2, varscan2
- EXPH5 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.163); catalogued as rs1405745884; called by muse, mutect2, varscan2
- FOLR2 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 104/608 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs761315273; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1051T>C p.W351R | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.298); catalogued as rs748818271; called by muse, mutect2, varscan2
- KCNA4 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs772880533, COSV60254930; called by muse, varscan2
- MRPS30 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273460644; called by muse, mutect2, varscan2
- OTOGL | c.2857G>T p.D953Y (on ENST00000547103; = p.D944Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101509448; called by muse, mutect2, varscan2
- PCDHA2 | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 99/448 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as rs1340196093; called by muse, mutect2, varscan2
- ZC3H7A | c.940A>G p.S314G | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs779834277; called by muse, mutect2, varscan2
- ZNF644 | c.1538A>G p.Q513R | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.229); catalogued as rs759517244; called by muse, mutect2, varscan2
- ACAD10 | c.1489G>T p.A497S | Missense Mutation (SNP) | VAF 70/400 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE4P | n.2154+2T>C | Splice Site (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.694T>A p.W232R | Missense Mutation (SNP) | VAF 87/502 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ANXA7 | c.707_724del p.I236_E242delinsK (on ENST00000372919 / NM_001320880.2; = p.I214_E220delinsK on NM_001156.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel
- APBB3 | c.641C>A p.A214D (on ENST00000357560 / NM_133173.2; = p.A221D on NM_006051.3) | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C11orf80 | c.170-5_171delinsTTTTTTT p.X57_splice | Splice Site (ONP) | VAF 6/31 reads (19%) | called by muse*, pindel
- CISH | c.383A>G p.N128S (on ENST00000348721 / NM_145071.4; = p.N145S on NM_013324.6) | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CTTN | c.396dup p.D133* | Frame Shift Ins (INS) | VAF 36/176 reads (20%) | called by mutect2, pindel, varscan2
- CUBN | c.794A>G p.D265G | Missense Mutation (SNP) | VAF 99/772 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DAAM2 | c.1831G>A p.V611M | Missense Mutation (SNP) | VAF 90/391 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- EIF2AK4 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 80/472 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- F5 | c.6152G>A p.R2051K | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FBRS | c.700T>C p.F234L (on ENST00000287468; = p.F754L on NM_001105079.3) | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FBXO24 | c.608T>A p.V203D (on ENST00000241071 / NM_033506.3; = p.V241D on NM_012172.5) | Missense Mutation (SNP) | VAF 111/452 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FERMT1 | c.1681T>A p.S561T | Missense Mutation (SNP) | VAF 131/634 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FOXD4L4 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 122/1262 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- GALNTL5 | c.345A>C p.E115D | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GMEB2 | c.340A>T p.N114Y | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR179 | c.1097G>A p.S366N (on ENST00000621958; = p.S365N on NM_001004334.4) | Missense Mutation (SNP) | VAF 108/475 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- GREB1 | c.2785C>A p.L929M | Missense Mutation (SNP) | VAF 134/595 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMB4 | c.1351G>A p.G451S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPCAT4 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- LPGAT1 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.813); called by muse, mutect2
- MAGEB10 | c.947A>C p.E316A | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MAPK14 | c.754T>C p.S252P | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MARF1 | c.1622G>A p.G541E | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAST1 | c.4194T>A p.D1398E | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDGA1 | c.596dup p.K200Efs*21 | Frame Shift Ins (INS) | VAF 69/279 reads (25%) | called by mutect2, pindel, varscan2
- MERTK | c.1101G>A p.W367* | Nonsense Mutation (SNP) | VAF 90/359 reads (25%) | called by muse, mutect2, varscan2
- MYO3A | c.3113dup p.F1039Vfs*3 | Frame Shift Ins (INS) | VAF 14/103 reads (14%) | called by mutect2, pindel, varscan2
- NAV3 | c.1840G>A p.V614I | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NR6A1 | c.510C>A p.S170R (on ENST00000487099 / NM_033334.4; = p.S166R on NM_001489.5) | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NUP210L | c.3922T>G p.S1308A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- OFD1 | c.2746T>C p.Y916H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR51I2 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAN2 | c.2253del p.E752Rfs*17 (on ENST00000425394 / NM_001127460.3; = p.E748Rfs*17 on NM_014871.5) | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- PBX3 | c.201-3del | Splice Region (DEL) | VAF 33/149 reads (22%) | called by mutect2, pindel, varscan2
- PCDHA5 | c.2270T>G p.V757G | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PCNT | c.4829T>A p.L1610* | Nonsense Mutation (SNP) | VAF 113/497 reads (23%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.3788C>A p.T1263K | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- POLR2H | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 86/413 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP1R26 | c.1651T>G p.L551V | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RBL2 | c.167T>A p.L56H | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RNF214 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 32/126 reads (25%) | called by muse, varscan2
- SERPINA6 | c.1031A>G p.K344R | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLC12A2 | c.1485T>G p.F495L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC16A7 | c.420T>A p.Y140* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2
- SLC3A1 | c.1828A>G p.M610V | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB1 | c.7526G>A p.G2509D | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- STAG1 | c.432T>A p.N144K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TDRD5 | c.2404G>T p.V802L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TM9SF2 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- TP53BP1 | c.1181del p.T394Sfs*24 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | called by mutect2, pindel, varscan2
- TPRKB | c.442-1G>A p.X148_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- TTC28 | c.6484T>A p.L2162I | Missense Mutation (SNP) | VAF 74/391 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- UBE3B | c.964del p.L322Sfs*6 | Frame Shift Del (DEL) | VAF 27/101 reads (27%) | called by mutect2, pindel, varscan2
- WASHC2A | c.1784T>G p.L595R | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- WDR36 | c.2299A>C p.N767H | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- WT1 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 151/759 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZBTB34 | c.893C>A p.A298D | Missense Mutation (SNP) | VAF 77/415 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF680 | c.1141dup p.E381Gfs*15 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by pindel, varscan2
- ZNF687 | c.1631dup p.L544Ffs*10 | Frame Shift Ins (INS) | VAF 62/323 reads (19%) | called by mutect2, pindel, varscan2
- ZNF714 | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- AUTS2 | c.3192T>C p.P1064= | Silent (SNP) | VAF 52/169 reads (31%) | called by muse, mutect2, varscan2
- BHMT2 | c.576T>C p.C192= | Silent (SNP) | VAF 53/209 reads (25%) | called by muse, mutect2, varscan2
- BOD1L1 | c.3993T>A p.T1331= | Silent (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- C11orf52 | c.183G>T p.G61= | Silent (SNP) | VAF 88/399 reads (22%) | catalogued as rs782429338; called by muse, mutect2, varscan2
- CHD8 | c.2949T>G p.T983= (on ENST00000646647 / NM_001170629.2; = p.T704= on NM_020920.4) | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- EFR3A | c.75T>G p.P25= | Silent (SNP) | VAF 45/188 reads (24%) | called by muse, mutect2, varscan2
- ENO4 | c.1182G>C p.L394= (on ENST00000622726; = p.L391= on NM_001242699.2) | Silent (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- FADS3 | c.1179G>A p.P393= | Silent (SNP) | VAF 84/400 reads (21%) | catalogued as rs531494466; called by muse, mutect2, varscan2
- KCTD20 | c.552C>A p.T184= | Silent (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- MGAM | c.4383C>A p.T1461= | Silent (SNP) | VAF 125/536 reads (23%) | catalogued as rs1210138272, COSV72075816; called by muse, mutect2, varscan2
- MROH9 | c.606G>C p.R202= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV63012198; called by muse, mutect2, varscan2
- NABP2 | c.156C>A p.I52= | Silent (SNP) | VAF 66/296 reads (22%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.2328G>A p.Q776= | Silent (SNP) | VAF 124/480 reads (26%) | catalogued as rs1354902623; called by muse, mutect2, varscan2
- PRR33 | c.849C>T p.S283= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- SLC5A5 | c.915G>A p.V305= | Silent (SNP) | VAF 156/795 reads (20%) | catalogued as rs1484899161; called by muse, mutect2, varscan2
- SSX2IP | c.1317T>C p.F439= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs1178121225; called by muse, mutect2, varscan2
- TLK2 | c.2058T>C p.S686= (on ENST00000326270 / NM_001284333.2; = p.S664= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- TTLL9 | c.547C>T p.L183= | Silent (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- WASHC2A | c.1785A>C p.L595= | Silent (SNP) | VAF 70/309 reads (23%) | called by muse, mutect2, varscan2
- ZNF319 | c.133C>T p.L45= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- AQP2 | c.*177G>T | 3'UTR (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- DCAF17 | c.*3610C>T | 3'UTR (SNP) | VAF 32/184 reads (17%) | called by muse, mutect2, varscan2
- DDHD1 | chr14:53152589 C>G | 5'Flank (SNP) | VAF 98/441 reads (22%) | called by muse, mutect2, varscan2
- IMMP2L | c.239+95219G>A | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2
- KCNAB2 | c.502+798del | Intron (DEL) | VAF 54/293 reads (18%) | called by mutect2, pindel, varscan2
- LNPEP | c.-15_-6del | 5'UTR (DEL) | VAF 27/116 reads (23%) | called by mutect2, pindel, varscan2
- MYCBP | c.15+74G>T | Intron (SNP) | VAF 53/229 reads (23%) | called by muse, mutect2, varscan2
- NSMF | c.780-10C>T | Intron (SNP) | VAF 107/440 reads (24%) | catalogued as rs564463059; called by muse, mutect2, varscan2
- PABPC4L | c.-98C>T | 5'UTR (SNP) | VAF 116/447 reads (26%) | called by muse, mutect2, varscan2
- RBBP7 | c.16+406G>T | Intron (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2
- SDSL | c.-143-1373_-143-1368del | Intron (DEL) | VAF 50/232 reads (22%) | called by pindel, varscan2
- SLC34A1 | c.841-26T>C | Intron (SNP) | VAF 160/801 reads (20%) | called by muse, mutect2, varscan2
- SLC7A7 | c.-180-203A>C | Intron (SNP) | VAF 63/259 reads (24%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.105G>T | RNA (SNP) | VAF 121/575 reads (21%) | catalogued as rs769455092; called by mutect2, varscan2
- TMEM254 | c.88-165_88-163del | Intron (DEL) | VAF 4/55 reads (7%) | catalogued as rs987452287; called by pindel, varscan2
- TPSD1 | chr16:1261417 G>A | 3'Flank (SNP) | VAF 81/387 reads (21%) | catalogued as rs533729880; called by muse, mutect2, varscan2
- ZNF286B | n.991dup | RNA (INS) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
